Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A3GJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A3GJ-01A (Primary Tumor).

[page 1 of 8]
Dual/Synchronous Primaries Noted		✓

PAGE:1

PATIENT: _____

LOC:

M/BED:

REG DR:

DIS:

SPEC #:

Obtained:

Subm Dx:

STATUS:

Received:

CLINICAL HISTORY:

CERVICAL CANCER

SPECIMEN/PROCEDURE:

1. SOFT TISSUES OF ABDOMEN - RIGHT BLADDER PILLER
2. LYMPH - RIGHT OBTURATOR
3. LYMPH - RIGHT EXTERNAL ILIAC
4. LYMPH - LEFT EXTERNAL ILIAC
5. LYMPH - LEFT COMMON ILIAC
6. LYMPH - LEFT OBTURATOR
7. LYMPH - LEFT PARA AORTIC
8. UTERUS - W/ CERVIX, BILAT TUBES, BILAT OVARIES
9. LYMPH - RIGHT COMMON ILIAC
10. LYMPH - RIGHT PARA AORTIC

ICD-0-3

IMPRESSION:

Carcinoma, squamous cell, large cell, Keratinizing 8071/3
Site: cervix, NOS C53.9

lw 11/29/11

- 1) SOFT TISSUE, RIGHT BLADDER PILLAR, BIOPSY:
- . Benign fibroadipose tissue.
- . Negative for malignancy.
- 2) LYMPH NODES, RIGHT OBTURATOR, REGIONAL DISSECTION:
- . Four benign lymph nodes (0/4).
- 3) LYMPH NODES, RIGHT EXTERNAL ILIAC, REGIONAL DISSECTION:
- . Five benign lymph nodes (0/5).
- 4) LYMPH NODE, LEFT EXTERNAL ILIAC, BIOPSY:
- . One benign lymph node (0/1).
- 5) LYMPH NODE, LEFT COMMON ILIAC, BIOPSY:
- . One benign lymph node (0/1).
- 6) LYMPH NODE, LEFT OBTURATOR, REGIONAL DISSECTION:
- . Nine benign lymph nodes (0/6).
- 7) LYMPH NODES, RIGHT PARA-AORTIC, REGIONAL DISSECTION:
- . Four benign lymph nodes (0/4).

*** CONTINUED ON NEXT PAGE ***

[page 2 of 8]
IMPRESSION: (continued)

UTERUS WITH CERVIX, BILATERAL TUBES AND OVARIES; RADICAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY:

CERVIX:

- . Invasive squamous cell carcinoma, large cell, keratinizing type; poorly differentiated. (Please see tumor checklist)
- . Tumor invades to a maximum depth of 6 mm (as measured from the base of the overlying epithelium); where the cervical stromal thickness is 18 mm.
- . No vascular space invasion identified.

ENDOMYOMETRIUM:

- . Endometrial polyp, benign (0.7 cm).
- . Atrophic pattern.
- . Negative for malignancy.

VAGINAL CUFF:

- . Benign squamous mucosa.
- . Negative for malignancy.

BILATERAL PARAMETRIA:

- . Benign fibroadipose tissue
- . Two benign lymph nodes (0/2).
- . Negative for malignancy.

BILATERAL OVARIES:

- . Benign physiologic changes.
- . Negative for malignancy.

BILATERAL FALLOPIAN TUBES:

- . Negative for malignancy.

9) LYMPH NODE, RIGHT COMMON ILIAC, BIOPSY:

- . One benign lymph node (0/1).

10) LYMPH NODES, RIGHT PARA-AORTIC, REGIONAL DISSECTION:

- . Two benign lymph nodes (0/2).

UTERINE CERVIX: TRACHELECTOMY, HYSTERECTOMY, PELVIC EXENTERATION

SPECIMEN

Cervix
Uterus corpus
Right ovary
Left ovary
Left fallopian tube, segment
Right fallopian tube, segment
Other: Regional lymph node dissection, soft tissue biopsy

PROCEDURE

Radical hysterectomy

** CONTINUED ON NEXT PAGE **

[page 3 of 8]
IMPRESSION: (continued)**TUMOR SIZE**

Greatest dimension: 3.5 x 2.2 x 1.4 cm

TUMOR SITE

Right superior quadrant (12-3 o'clock)

Right inferior quadrant (3-6 o'clock)

Left inferior quadrant (6-9 o'clock)

Left anterior quadrant (9-12 o'clock)

HISTOLOGIC TYPE

Squamous cell carcinoma

Keratinizing

HISTOLOGIC GRADE

G3: Poorly differentiated

MARGINS**Resection Margin**

Margins uninvolved by invasive carcinoma

Distance of invasive carcinoma from margin: 12 mm

Specify location, if possible: Deep soft tissue margin at 4 o'clock (right inferior quadrant)

DEPTH OF INVASION

The maximal thickness of the cervical stromal invasion is 6 mm.

The thickness of the cervix in the area of maximal tumor invasion is 18 mm.

The percentage of cervical stromal invasion is 33%.

PARAMETRIAL INVOLVEMENT

No parametrial involvement.

LYMPH-VASCULAR INVASION

Not identified

PATHOLOGIC STAGING (pTNM [FIGO])**PRIMARY TUMOR (pT)**

pT1b1[IB1]: Clinically visible lesion < 4.0 cm in greatest dimension

REGIONAL LYMPH NODES (pN)

pN0: No regional lymph node metastasis

DISTANT METASTASIS (pM)

Not applicable

** CONTINUED ON NEXT PAGE **

[page 4 of 8]
IMPRESSION: (continued)**ADDITIONAL PATHOLOGIC FINDINGS****Intraepithelial neoplasia****Severe squamous dysplasia, CIN III****ANCILLARY STUDIES****None****Dictated by:****Entered:****COMMENT:**

has reviewed representative slides and concurs with the above impression.

Entered:**SPECIAL STAINS/PROCEDURES:**

The following immunohistochemical stain was performed with appropriate positive and negative controls on block 8T:

p16:

Strongly positive in tumor cells and dysplastic squamous cells; few, patchy positive endocervical glandular cells

The overall pattern is consistent with invasive squamous cell carcinoma and associated severe squamous dysplasia.

Dictated by:**GROSS DESCRIPTION:**

1. Received in formalin labeled with the patient's name and right bladder pillar. Received is a pale pink to red tan tissue fragment that is 1.5 x 0.9 x 0.6 cm. The specimen will be serially sectioned and entirely submitted in cassette #1.
2. Received in formalin labeled with the patient's name and right obturator. Received is a 4 x 2 x 1 cm portion of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, 4 possible lymph nodes are identified ranging from 0.5-2.1 cm in greatest dimension. Specimens is submitted as follows:

CASSETTE 2A: 3 possible lymph nodes
CASSETTE 2B-2C: One lymph node bisected
3. Received in formalin labeled with the patient's name and right external iliac. Received is a 4.3 x 2 x 0.7 cm portion of slightly hemorrhagic yellow gold fibroadipose

**** CONTINUED ON NEXT PAGE ****

[page 5 of 8]
GROSS DESCRIPTION: (continued)

sue. The specimen is dissected for possible lymph nodes, 5 possible lymph nodes are identified ranging from 0.7-2 cm in greatest dimension. Specimens is submitted as follows:

CASSETTE 3A: 2 possible lymph nodes
CASSETTE 3B: One lymph node bisected
CASSETTE 3C: One lymph node bisected
CASSETTE 3D: One lymph node bisected

4. Received in formalin labeled with the patient's name and left external iliac. Received is a 2 x 1.4 x 1 cm portion of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, one possible lymph node identified that is 1.5 x 0.7 x 0.5 cm. Specimen will be submitted as follows:

CASSETTE 4: One lymph node bisected

5. Received in formalin labeled with the patient's name and left common iliac. Received is a 3.7 x 1.1 x 0.7 cm portion of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, one possible lymph node identified that is 1.7 x 0.7 x 0.7 cm. Specimens is submitted as follows:

CASSETTE 5: One lymph node bisected

6. Received in formalin labeled with the patient's name and left obturator. Received is a 4.7 x 2.1 x 3.2 cm aggregate of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, 8 possible lymph nodes are identified ranging from 0.7-2.9 cm in greatest dimension. Specimens is submitted as follows:

CASSETTE 6A: 4 possible lymph nodes
CASSETTE 6B: One lymph node bisected
CASSETTE 6C: One lymph node bisected
CASSETTE 6D: One lymph node bisected
CASSETTE 6E-6G: One lymph node serially sectioned

7. Received in formalin labeled with the patient's name and right para-aortic. Received is a 3 x 2 x 0.9 cm aggregate of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, 4 possible lymph nodes are identified ranging from 0.6 x 2.5 cm in greatest dimension. Specimens is submitted as follows:

CASSETTE 7A: 3 possible lymph nodes
CASSETTE 7B: One lymph node bisected

8. Received in formalin labeled with the patient's name and "uterus with cervix, bilateral tubes and ovaries," is an 130 gram radical hysterectomy specimen consisting of 9 x 4.5 x 3 cm uterus with attached 3 x 0.5 cm left fallopian tube fragment, 3.2 x 1.2 x 1.1 cm left ovary, 3.3 x 0.4 cm fragment of right fallopian tube, and 2.7 x 1.3 x 1.7 cm right ovary. The left parametrial tissue measures 2.5 x 2 x 1 cm, and the right parametrial tissue

** CONTINUED ON NEXT PAGE **

[page 6 of 8]
GROSS DESCRIPTION: (continued)

Measures 2.4 x 1.4 x 1.3 cm. The external surface of the specimen including parametrial tissue is inked black for identification. The right and left parametrial tissues are submitted in entirety. The ectocervix measures 4.3 x 3.2 cm. There is a 3.5 x 3.2 x 1.4 pink-tan polypoid exophytic mass arising from the right anterior portion of the cervix. The most posterior aspect of the cervix is arbitrarily designated as 12:00. The mass extends from 2:00 to 7:00. The external OS is deformed by the fungating mass but remains patent. The tumor is grossly 2.4 cm from the closest vaginal margin (3:00). The external surface of the tumor is tan and roughened and focally ulcerated. The cut surface is tan, firm with friable areas. Grossly, the mass appears to extend into the cervical stroma to a maximum depth of 0.7 cm. The tumor appears to extend into the endocervical canal. The remainder of the cervical mucosa is tan-pink, smooth and unremarkable. The endocervical canal measures 3.3 cm in length and is covered by tan herring bone mucosa. The endometrial cavity measures 3.2 cm in length x 2.1 cm from cornu to cornu and is covered by a tan, predominantly flat mucosa with foci of hemorrhage. There is a 0.7 x 0.6 x 0.2 cm polypoid projection from the posterior endometrial wall. The myometrium is tan, firm and unremarkable with a maximum thickness of 1.3 cm. The left and right fallopian tubes are fragmented and not patent. No fimbriated ends are identified. The left ovary is tan-yellow to tan-white, smooth and unremarkable. The cut surface is tan to tan-yellow to tan-white with multiple corpora albicantia. There is a 1.1 cm in diameter simple unilocular cyst in the left ovary. The right ovary is tan to tan-yellow with a smooth external surface. The cut surface is tan to tan-white with multiple corpora albicantia. Representative sections are submitted as follows:

CASSETTES 8A-8D:	Left parametrial tissue in entirety.
CASSETTES 8E-8J:	Right parametrial tissue in entirety.
CASSETTE 8K:	Cervix at 3:00 with perpendicular vaginal margin.
CASSETTE 8L:	Posterior vaginal mucosal margin from 9:00 to 3:00, en face.
CASSETTE 8M:	Anterior vaginal mucosal margin from 3:00 to 9:00, en face.
CASSETTE 8N:	Cervix at 4:00 with tumor.
CASSETTE 8P:	Cervix at 5:00 with tumor.
CASSETTE 8Q:	Cervix at 6:00.
CASSETTE 8R:	Anterior endocervical canal (6:00).
CASSETTE 8S:	Anterior lower uterine segment.
CASSETTE 8T:	Cervix at 9:00.
CASSETTE 8U:	Cervix at 12:00.
CASSETTE 8V:	Posterior endocervical canal and lower uterine segment (12:00).
CASSETTE 8W:	Anterior uterine corpus, full thickness.
CASSETTE 8X:	Posterior uterine corpus, full thickness, with polyp.
CASSETTE 8Y:	Left ovary and fallopian tube.
CASSETTE 8Z:	Right ovary and fallopian tube.
CASSETTE 8AA, 8BB:	Cervix at 11:00.
CASSETTE 8CC:	Cervix at 12:00.

9. Received in formalin labeled with the patient's name and right common iliac. Received is a 2.2 x 1.3 x 0.5 cm portion of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, one possible lymph node is identified

** CONTINUED ON NEXT PAGE **

[page 7 of 8]
GROSS DESCRIPTION: (continued)

is 0.5 x 0.3 x 0.3 cm. Specimens is submitted as follows:

CASSETTE 9A: One possible lymph node

10. Received in formalin labeled with the patient's name and right para-aortic. Received is a 3 x 1.2 x 0.7 cm portion of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, 2 possible lymph nodes are identified ranging from 1.1-1 cm in greatest dimension. Specimens is submitted as follows:

CASSETTE 10A: One lymph node bisected

CASSETTE 10B: One lymph node bisected

Prim: 8N

Dictated by:

Entered:

COPIES TO:

Undefined Provider

CPT Codes:

LYMPH NODE, REGIONAL RESECT/88307/5, UTERUS W/WO ADNEXAE, TUMOR-88309, IHC P16-88342,
LYMPH NODE BIOPSY/88305/3, SOFT TISSUE BIOPSY/88305

** CONTINUED ON NEXT PAGE **

[page 8 of 8]
ICD9 Codes:

.9

Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by:

Physicians

^^ END OF REPORT ^^

Source: NCI Genomic Data Commons file 1a573d71-2af6-49c1-a335-da430ad047c4 (TCGA-EK-A3GJ.45318527-2DCC-472C-8712-8639CCF4931D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).